Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A3A4, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A3A4-01A (Primary Tumor).

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

Left lobe liver (2195 grams, 26 x 16 x 9 cm), separately submitted tissue from Segment V liver (30 grams, 5 x 4 x 3 cm), needle biopsy from Segment V liver No.1 (2 mm) and No.2 (7 mm), left periportal lymph node (2.1 x 1.3 x 0.8 cm) and gallbladder (8 x 3.5 x 2 cm). A1, B1, C1, C2, C3, C4, C5, C6, C7, D1, D2, E1

DIAGNOSIS:

Liver, left lobe, excision: Grade 3 (of 4), hepatocellular carcinoma, usual type, forming a 25 x 16 x 9 cm multinodular mass. The tumor is located in left lobe. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 1.2 cm microscopically. Extramural vascular invasion is not identified. The tumor is encapsulated by a 0.5 cm thick fibrous capsule. The approximate percent of necrosis is 10%. The non-neoplastic liver will be assessed on permanent sections and an addendum will be issued.

Liver, Segment V, excision: Grade 3 (of 4) hepatocellular carcinoma, forming a mass (3 x 2 x 1.8 cm). The margins are negative for tumor.

Liver, Segment V, needle biopsy #1: Hemangioma.

Liver, Segment V, needle biopsy #2: Negative for tumor.

Lymph node, periportal, excision: A single benign lymph node is identified.

Gallbladder, cholecystectomy: No diagnostic abnormalities.

ADDENDUM:

Permanent sections of the adjacent non-neoplastic liver tissue show no diagnostic abnormalities. An iron stain and PAS-D are negative.

Seen with Dr.

ICD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22.0

9/22/11

Source: NCI Genomic Data Commons file f8c127ad-9e24-436d-8418-48a4d9473468 (TCGA-DD-A3A4.C755324B-9B82-4319-BDD8-EB8A24107AAC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).